Somatic mutation profile of cancer-model specimen HCM-CSHL-0818-C56-85P (3D Organoid; aliquot HCM-CSHL-0818-C56-85P-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0818-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 62.2 years (22,709 days).
Specimen HCM-CSHL-0818-C56-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97b9cba0-f703-4f26-9821-b87c62d2a4ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0818-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0818-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cc90ad4-c6d6-494a-adb4-834d345eefe3

The open-access MAF lists 136 somatic variants for this specimen: 100 protein-altering or splice-affecting, 27 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 27, Nonsense Mutation 8, Intron 5, Frame Shift Del 4, Splice Site 3, 5'Flank 2, Frame Shift Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD3 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs766791159, COSV64642475; called by muse, mutect2, varscan2
- ACACB | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1437383134; called by muse, mutect2
- CACNA1E | c.3090T>G p.S1030R | Missense Mutation (SNP) | VAF 227/752 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as rs746949281; called by muse, mutect2, varscan2
- CCDC141 | c.3694A>C p.M1232L | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.094); catalogued as COSV99836531; called by muse, mutect2
- CCDC172 | c.612A>G p.I204M | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs1402715200; called by muse, mutect2, varscan2
- CD79A | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 145/346 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs1202927044; called by muse, mutect2, varscan2
- CFAP157 | c.1511T>C p.L504P | Missense Mutation (SNP) | VAF 91/419 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1466731753, COSV58852350; called by muse, mutect2, varscan2
- CNTNAP1 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 331/333 reads (99%) | catalogued as rs144659252, COSV99226269; called by muse, mutect2, varscan2
- COL11A2 | c.4978C>T p.R1660C (on ENST00000341947 / NM_080680.3; = p.R1553C on NM_080679.2) | Missense Mutation (SNP) | VAF 262/838 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs546841812; called by muse, mutect2, varscan2
- CROCC | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 187/530 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as rs759425058; called by muse, mutect2, varscan2
- EVPL | c.4109T>A p.V1370E | Missense Mutation (SNP) | VAF 226/604 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs751058801; called by muse, mutect2, varscan2
- EVX2 | c.950G>C p.R317P | Missense Mutation (SNP) | VAF 165/693 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1395678401; called by muse, mutect2, varscan2
- FAM135B | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 109/797 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99427310; called by muse, mutect2, varscan2
- FMN2 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 116/627 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100143999; called by muse, mutect2, varscan2
- GLI2 | c.2761C>T p.R921W (on ENST00000361492 / NM_001374353.1; = p.R938W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/601 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs900449843; called by muse, mutect2, varscan2
- IFIT2 | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 103/133 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs543713702, COSV51080522; called by muse, mutect2, varscan2
- KCNB1 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.742); catalogued as rs1259001599, COSV65565747, COSV65566820; called by muse, mutect2, varscan2
- LAMA2 | c.6062G>T p.G2021V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as COSV101370878; called by muse, mutect2
- LCT | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 143/557 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867715897, COSV51548135; called by muse, mutect2, varscan2
- LIMS1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs776581560; called by muse, mutect2, varscan2
- LOXL3 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 203/767 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775264232, COSV104382391; called by muse, mutect2, varscan2
- LRRC70 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 40/125 reads (32%) | catalogued as rs752188484; called by muse, mutect2, varscan2
- LTN1 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs750217371, COSV100797882; called by muse, mutect2, varscan2
- MUC16 | c.37792C>A p.L12598M | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1016852528; called by muse, mutect2
- MYOG | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 19/457 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs149914557; called by muse, mutect2
- NCAM2 | c.326del p.L109Wfs*58 | Frame Shift Del (DEL) | VAF 41/233 reads (18%) | catalogued as COSV99523298; called by mutect2, pindel, varscan2
- NELL1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 160/237 reads (68%) | SIFT tolerated (0.47); PolyPhen benign (0.103); catalogued as rs780205351, COSV100121398; called by muse, mutect2, varscan2
- NLRP5 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 62/472 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV66764197, COSV66764553; called by muse, mutect2, varscan2
- PDILT | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 60/320 reads (19%) | catalogued as rs139247719, COSV56700444; called by muse, mutect2, varscan2
- RABEP2 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs202177661, COSV62870351, COSV62871233; called by muse, mutect2, varscan2
- SUGP1 | c.1623C>G p.F541L | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs1312881404; called by muse, mutect2, varscan2
- TBX15 | c.419+1G>T p.X140_splice (on ENST00000369429 / NM_001330677.2; = p.X34_splice on NM_152380.3) | Splice Site (SNP) | VAF 30/195 reads (15%) | catalogued as COSV52870918; called by muse, mutect2
- TSPEAR | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 214/774 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100555716; called by muse, mutect2, varscan2
- TTN | c.11177A>C p.K3726T (on ENST00000591111; = p.K3680T on NM_003319.4) | Missense Mutation (SNP) | VAF 56/669 reads (8%) | catalogued as COSV60139639; called by muse, mutect2
- YME1L1 | c.1604C>T p.A535V (on ENST00000326799 / NM_139312.3; = p.A478V on NM_014263.4) | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58758537; called by muse, mutect2
- ZBP1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs201702091, COSV59061549; called by muse, mutect2, varscan2
- ZFHX4 | c.9925G>A p.G3309S | Missense Mutation (SNP) | VAF 142/588 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs775658313; called by muse, mutect2, varscan2
- ABCB8 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 31/468 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- AC244197.3 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 138/297 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- AL136295.1 | c.1133T>G p.F378C | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- AP002495.1 | c.317G>T p.G106V (on ENST00000528511; = p.G37V on NM_001375848.1) | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCORL1 | c.4253G>A p.G1418E | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BICC1 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2
- CACNA1E | c.5776del p.V1926Ffs*4 | Frame Shift Del (DEL) | VAF 64/461 reads (14%) | called by mutect2, pindel, varscan2
- CADPS | c.1360G>C p.A454P | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CAPN11 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 93/366 reads (25%) | called by muse, mutect2, varscan2
- CCDC8 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 120/580 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.444); called by muse, varscan2
- CDC5L | c.1574T>C p.I525T | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CEACAM18 | c.438C>A p.S146R | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CNGA3 | c.1507T>C p.F503L | Missense Mutation (SNP) | VAF 118/511 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CPSF3 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 103/583 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- CRH | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 224/1197 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSMD3 | c.7979A>G p.D2660G (on ENST00000297405 / NM_001363185.1; = p.D2556G on NM_052900.3) | Missense Mutation (SNP) | VAF 39/692 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.06); called by muse, mutect2
- DCAF5 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 142/316 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- EHMT2 | c.1482C>A p.C494* | Nonsense Mutation (SNP) | VAF 125/831 reads (15%) | called by muse, mutect2, varscan2
- EMX1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 20/738 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2
- EPAS1 | c.875G>T p.S292I | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBRSL1 | c.1975C>G p.P659A | Missense Mutation (SNP) | VAF 19/505 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2
- FCRL3 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 228/286 reads (80%) | SIFT tolerated (0.3); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- FLG | c.10795G>A p.G3599S | Missense Mutation (SNP) | VAF 36/625 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2
- GLE1 | c.1313-1G>C p.X438_splice | Splice Site (SNP) | VAF 77/169 reads (46%) | called by muse, mutect2, varscan2
- GOLGA6L6 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 168/562 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- GRB14 | c.454T>G p.F152V | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQSEC2 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 211/490 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ITGB1BP2 | c.653G>T p.C218F | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KRT85 | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 58/884 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- LCE2D | c.280_281del p.S94* | Frame Shift Del (DEL) | VAF 152/596 reads (26%) | called by pindel, varscan2
- LRP1B | c.6862T>G p.S2288A | Missense Mutation (SNP) | VAF 16/550 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2
- MRC1 | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MS4A2 | c.418G>C p.A140P | Missense Mutation (SNP) | VAF 38/536 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2
- MTMR8 | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NEB | c.403-15_404del p.X135_splice | Splice Site (DEL) | VAF 51/360 reads (14%) | called by mutect2, pindel, varscan2
- NPAS1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 160/304 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PQBP1 | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRSS36 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 155/397 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRM | c.2987T>G p.M996R | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RBM46 | c.353T>A p.I118N | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RUNX1T1 | c.408del p.F136Lfs*9 (on ENST00000265814 / NM_001198628.1; = p.F109Lfs*9 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 137/1029 reads (13%) | called by mutect2, pindel, varscan2
- RUSC1 | c.2198T>A p.L733* (on ENST00000368352 / NM_001105203.2; = p.L264* on NM_014328.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 100/388 reads (26%) | called by muse, mutect2, varscan2
- SETD1A | c.2518G>C p.A840P | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC30A3 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 42/933 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- SPAG1 | c.2564A>G p.Q855R | Missense Mutation (SNP) | VAF 86/778 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SRSF11 | c.1358dup p.E454Gfs*10 | Frame Shift Ins (INS) | VAF 398/557 reads (71%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1399T>C p.Y467H (on ENST00000367255 / NM_182961.4; = p.Y474H on NM_033071.3) | Missense Mutation (SNP) | VAF 124/337 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT11 | c.721G>C p.V241L | Missense Mutation (SNP) | VAF 177/481 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TAF11L8 | c.295T>C p.S99P | Missense Mutation (SNP) | VAF 479/895 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- TAMM41 | c.1282T>C p.S428P | Missense Mutation (SNP) | VAF 22/556 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- TBX15 | c.419G>A p.R140K (on ENST00000369429 / NM_001330677.2; = p.R34K on NM_152380.3) | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TCAF2 | c.2207A>G p.E736G | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2
- TENM2 | c.8084T>G p.V2695G (on ENST00000518659 / NM_001122679.2; = p.V2456G on NM_001080428.3) | Missense Mutation (SNP) | VAF 249/505 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- THBS2 | c.2741T>G p.L914R | Missense Mutation (SNP) | VAF 47/518 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THNSL2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 31/607 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.122); called by muse, mutect2
- TTC9 | c.242A>T p.H81L | Missense Mutation (SNP) | VAF 232/499 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- UGT2B15 | c.671G>A p.W224* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- UNC5B | c.1786G>C p.G596R | Missense Mutation (SNP) | VAF 26/435 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- VCAN | c.8954G>T p.G2985V | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- WDR47 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 73/227 reads (32%) | called by muse, mutect2, varscan2
- ZBTB33 | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 159/361 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZFHX3 | c.5060G>A p.S1687N | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.081); called by muse, varscan2
- ZSCAN20 | c.2914T>G p.S972A | Missense Mutation (SNP) | VAF 125/451 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- AP002495.1 | c.318C>T p.G106= (on ENST00000528511; = p.G37= on NM_001375848.1) | Silent (SNP) | VAF 40/370 reads (11%) | catalogued as COSV73222869; called by muse, mutect2, varscan2
- C8A | c.72G>T p.V24= | Silent (SNP) | VAF 42/435 reads (10%) | called by muse, mutect2, varscan2
- CACTIN | c.1131C>T p.L377= | Silent (SNP) | VAF 23/383 reads (6%) | catalogued as rs867181065; called by muse, mutect2
- CILP2 | c.153G>A p.E51= | Silent (SNP) | VAF 129/294 reads (44%) | called by muse, mutect2, varscan2
- DNER | c.1533C>G p.S511= | Silent (SNP) | VAF 61/348 reads (18%) | called by muse, mutect2, varscan2
- EGLN3 | c.432C>A p.R144= | Silent (SNP) | VAF 14/318 reads (4%) | catalogued as COSV99164407; called by muse, mutect2
- ITPR1 | c.1260C>T p.T420= (on ENST00000354582; = p.T405= on NM_002222.7) | Silent (SNP) | VAF 61/196 reads (31%) | called by muse, mutect2, varscan2
- MARF1 | c.4608C>T p.L1536= | Silent (SNP) | VAF 113/321 reads (35%) | catalogued as rs770662256; called by muse, mutect2, varscan2
- MYB | c.1563C>G p.P521= | Silent (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- OMP | c.399C>A p.A133= | Silent (SNP) | VAF 172/496 reads (35%) | called by muse, varscan2
- PCDHGA12 | c.2235G>C p.G745= | Silent (SNP) | VAF 167/353 reads (47%) | catalogued as COSV52759301; called by muse, mutect2, varscan2
- PDE1C | c.2124A>G p.R708= | Silent (SNP) | VAF 52/173 reads (30%) | called by muse, mutect2, varscan2
- PLEC | c.13260C>T p.I4420= (on ENST00000322810 / NM_201380.4; = p.I4310= on NM_000445.5) | Silent (SNP) | VAF 205/1049 reads (20%) | catalogued as rs782370693; called by muse, mutect2, varscan2
- PRR29 | c.225T>A p.P75= | Silent (SNP) | VAF 36/488 reads (7%) | called by muse, mutect2
- PTPN5 | c.1194C>A p.I398= | Silent (SNP) | VAF 56/360 reads (16%) | catalogued as COSV62125484; called by muse, mutect2, varscan2
- ROPN1 | c.459G>A p.S153= | Silent (SNP) | VAF 34/236 reads (14%) | catalogued as rs750341418; called by muse, mutect2, varscan2
- RTN4IP1 | c.267T>C p.N89= | Silent (SNP) | VAF 71/171 reads (42%) | called by muse, mutect2, varscan2
- SLC7A1 | c.1405T>C p.L469= | Silent (SNP) | VAF 139/446 reads (31%) | catalogued as rs761908044; called by muse, mutect2, varscan2
- STK32A | c.837G>A p.P279= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as rs774101281; called by muse, mutect2, varscan2
- SUGP1 | c.1836C>G p.L612= | Silent (SNP) | VAF 491/926 reads (53%) | called by muse, mutect2, varscan2
- SYNPO2 | c.1515C>T p.I505= | Silent (SNP) | VAF 28/390 reads (7%) | catalogued as rs779306751; called by muse, mutect2
- TDRD15 | c.2931C>G p.P977= | Silent (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- THBS2 | c.735C>A p.R245= | Silent (SNP) | VAF 56/618 reads (9%) | called by muse, mutect2
- TLX2 | c.147G>A p.A49= | Silent (SNP) | VAF 260/959 reads (27%) | catalogued as rs1462911981; called by muse, mutect2, varscan2
- TP53BP1 | c.4779A>T p.G1593= | Silent (SNP) | VAF 16/536 reads (3%) | called by muse, mutect2
- ZEB2 | c.1728C>T p.N576= | Silent (SNP) | VAF 100/450 reads (22%) | catalogued as rs1041704975; called by muse, mutect2, varscan2
- ZXDC | c.21C>T p.L7= | Silent (SNP) | VAF 20/400 reads (5%) | catalogued as COSV60447431; called by muse, mutect2
- AL132655.6 | n.77C>T | RNA (SNP) | VAF 34/356 reads (10%) | called by muse, mutect2
- ASIC2 | c.556-179511C>T | Intron (SNP) | VAF 40/420 reads (10%) | catalogued as COSV56769843; called by muse, mutect2
- MIR296 | chr20:58819171 C>A | 5'Flank (SNP) | VAF 92/242 reads (38%) | called by muse, mutect2, varscan2
- MIR296 | chr20:58819172 C>T | 5'Flank (SNP) | VAF 91/243 reads (37%) | called by muse, mutect2, varscan2
- PKHD1 | c.*2329A>G | 3'UTR (SNP) | VAF 12/243 reads (5%) | called by muse, mutect2
- SLC22A23 | c.1579+143G>C | Intron (SNP) | VAF 115/469 reads (25%) | called by muse, mutect2, varscan2
- SON | c.6657+230G>A | Intron (SNP) | VAF 128/364 reads (35%) | catalogued as rs185513323; called by muse, mutect2, varscan2
- SPOCD1 | c.1869-158G>T | Intron (SNP) | VAF 28/705 reads (4%) | called by muse, mutect2
- ZDHHC11 | c.784+160C>T | Intron (SNP) | VAF 40/313 reads (13%) | called by muse, mutect2, varscan2
